Somatic mutation profile of tumor specimen TCGA-BJ-A2N8-01A (aliquot TCGA-BJ-A2N8-01A-11D-A18F-08) from TCGA case TCGA-BJ-A2N8, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 30.2 years (11,024 days).
Specimen TCGA-BJ-A2N8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40dd5336-be08-4360-8178-d12cc5721a5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A2N8-10A (Blood Derived Normal), aliquot TCGA-BJ-A2N8-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4465c37-2256-42d1-aac2-1ee0944d26af

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 63/177 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDH7 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1286586160, COSV59884783, COSV59891309; called by muse, mutect2, varscan2
- FKBPL | c.829C>G p.R277G | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV64322579; called by muse, mutect2
- REXO2 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99771775; called by mutect2, varscan2
- SCN9A | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 14/325 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1164206681, COSV57612535; called by muse, mutect2
- BEX3 | c.177G>C p.G59= | Silent (SNP) | VAF 10/282 reads (4%) | catalogued as COSV55421358; called by muse, mutect2
- DOCK11 | c.5868T>C p.N1956= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as COSV52240529; called by muse, mutect2, varscan2
